Somatic mutation profile of tumor specimen TCGA-D1-A2G5-01A (aliquot TCGA-D1-A2G5-01A-11D-A17D-09) from TCGA case TCGA-D1-A2G5, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 50.2 years (18,322 days).
Specimen TCGA-D1-A2G5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c410081-15a2-4318-8ee8-191765b35e2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A2G5-10A (Blood Derived Normal), aliquot TCGA-D1-A2G5-10A-01D-A17D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d2e0a24-1b43-4afd-a236-3255b5b2aa5d

The open-access MAF lists 244 somatic variants for this specimen: 181 protein-altering or splice-affecting, 57 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 122, Silent 57, Frame Shift Del 36, Nonsense Mutation 11, In Frame Del 5, Intron 4, Frame Shift Ins 3, Splice Site 2, Splice Region 2, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL2A1 | c.2818C>T p.R940* | Nonsense Mutation (SNP) | VAF 3/42 reads (7%) | catalogued as rs1057524114, COSV61535838; ClinVar: pathogenic; called by muse, mutect2
- PTEN | c.370T>A p.C124S | Missense Mutation (SNP) | VAF 72/124 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CD097201, CM971271, COSV64288968, COSV64294667, COSV64296578, COSV64297040; called by muse, mutect2, varscan2
- SOX17 | c.1208G>T p.S403I | Missense Mutation (SNP) | VAF 45/72 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52024163; called by muse, mutect2, varscan2
- ADAMTSL1 | c.117G>T p.W39C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99444025, COSV99444907; called by muse, mutect2, varscan2
- AKAP8 | c.1988C>G p.A663G | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV99512195; called by muse, mutect2, varscan2
- AMN | c.86A>T p.D29V | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as COSV100141591, COSV54486970; called by muse, mutect2
- AMN1 | c.553A>G p.I185V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99861704; called by muse, mutect2, varscan2
- ARFGAP3 | c.896del p.N299Mfs*22 | Frame Shift Del (DEL) | VAF 15/48 reads (31%) | catalogued as rs774441374, COSV54310368; called by mutect2, varscan2
- ATP6V1C1 | c.1108G>A p.V370M | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1317485078, COSV101215160; called by muse, mutect2
- ATP8B4 | c.857G>A p.C286Y | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.506); catalogued as COSV99467563; called by muse, mutect2, varscan2
- BCAS4 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs771780945, COSV99372815; called by muse, mutect2, varscan2
- BCORL1 | c.4904C>T p.S1635F | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99500998; called by muse, mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 7/55 reads (13%) | catalogued as rs1455506786, COSV59000653; called by mutect2, pindel, varscan2
- C16orf78 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV100147973, COSV54556114; called by muse, mutect2, varscan2
- CANX | c.1305del p.F435Lfs*12 | Frame Shift Del (DEL) | VAF 15/82 reads (18%) | catalogued as rs760711956; called by mutect2, varscan2
- CASKIN2 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs140678295; called by muse, mutect2
- CAT | c.1540C>T p.Q514* | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | catalogued as COSV99573479; called by muse, mutect2, varscan2
- CDC42BPB | c.2597G>A p.R866H | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100775619; called by muse, mutect2, varscan2
- CDCP2 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.788); catalogued as rs778829789, COSV100313353; called by muse, mutect2, varscan2
- CLCA4 | c.544del p.I182Sfs*56 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | catalogued as rs760255767; called by mutect2, varscan2
- CNNM2 | c.274del p.A92Rfs*4 | Frame Shift Del (DEL) | VAF 11/102 reads (11%) | catalogued as rs768722573; called by mutect2, pindel, varscan2
- COL16A1 | c.2810G>A p.G937E | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99595482, COSV99595503; called by muse, mutect2, varscan2
- CPAMD8 | c.5524G>A p.V1842M (on ENST00000651564; = p.V1795M on NM_015692.5) | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.514); catalogued as rs1432653139, COSV99935426; called by muse, mutect2
- CREB3L4 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs766639918; called by muse, mutect2
- CSNK1E | c.710T>G p.I237S | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.923); catalogued as COSV100725099; called by muse, mutect2
- CSNK2A2 | c.430-2A>G p.X144_splice | Splice Site (SNP) | VAF 20/80 reads (25%) | catalogued as COSV99345485; called by muse, mutect2, varscan2
- CTCF | c.1432G>T p.E478* | Nonsense Mutation (SNP) | VAF 44/98 reads (45%) | catalogued as COSV50463975, COSV99866622; called by muse, mutect2, varscan2
- CUL9 | c.3970G>A p.A1324T | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.842); catalogued as COSV99336073; called by muse, mutect2, varscan2
- DACT1 | c.2120C>T p.A707V | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV60019815; called by muse, mutect2, varscan2
- DCC | c.1926C>G p.S642R | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100503170; called by muse, mutect2, varscan2
- DHX35 | c.1882A>C p.R628= | Splice Region (SNP) | VAF 7/41 reads (17%) | catalogued as COSV99327334; called by muse, mutect2, varscan2
- DISP1 | c.2947G>T p.G983C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99452227; called by muse, mutect2, varscan2
- DNAH11 | c.6190G>A p.D2064N | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756809691, COSV60955272; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJC6 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.255); catalogued as rs141833490; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 10/96 reads (10%) | catalogued as rs782552436; called by mutect2, pindel
- EGFR | c.1873A>G p.T625A | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV99295137; called by muse, mutect2, varscan2
- ELOA2 | c.988C>T p.H330Y | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.244); catalogued as COSV99798173; called by muse, mutect2, varscan2
- EPB41L2 | c.579G>T p.E193D | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.253); catalogued as COSV100441058; called by muse, mutect2
- ERICH3 | c.4152A>C p.E1384D | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV100445838; called by muse, mutect2
- ESPL1 | c.3182G>A p.C1061Y | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); catalogued as COSV99229796; called by muse, mutect2, varscan2
- FAM13B | c.29G>A p.S10N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99221847; called by muse, mutect2, varscan2
- FAM189A2 | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as COSV99975390; called by muse, mutect2, varscan2
- FAT1 | c.12497C>T p.A4166V | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs376106855; called by muse, mutect2, varscan2
- FAT1 | c.9683del p.P3228Lfs*42 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs1010116749; called by mutect2, pindel, varscan2
- FBXL18 | c.1130C>T p.T377I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as COSV101212121; called by muse, mutect2, varscan2
- FBXL18 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs770719005, COSV101212123; called by muse, mutect2, varscan2
- FBXL7 | c.1294C>T p.R432W | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100308779, COSV61651948; called by muse, mutect2, varscan2
- FBXO31 | c.1054A>T p.I352F | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV100291619; called by muse, mutect2, varscan2
- FBXO41 | c.1888_1890del p.K630del | In Frame Del (DEL) | VAF 14/60 reads (23%) | catalogued as rs767370426; called by pindel, varscan2
- FCGR1A | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs782702206, COSV64985503; called by muse, mutect2
- FMNL2 | c.1588C>T p.P530S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.294); catalogued as COSV99980915; called by muse, mutect2, varscan2
- FXYD5 | c.80C>T p.T27I | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99545058; called by muse, mutect2
- GLB1L2 | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1329556403, COSV100335501; called by muse, mutect2, varscan2
- GLB1L3 | c.1233del p.V412* | Frame Shift Del (DEL) | VAF 6/65 reads (9%) | catalogued as rs758614894; called by mutect2, pindel
- GPATCH11 | c.654G>T p.E218D (on ENST00000409774; = p.E196D on NM_174931.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV56135152; called by muse, mutect2, varscan2
- GRIN3A | c.1497G>T p.Q499H | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100701844; called by muse, mutect2
- GRIPAP1 | c.682C>A p.L228I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.89); catalogued as COSV100904380; called by muse, mutect2, varscan2
- GRM7 | c.2575C>T p.R859W | Missense Mutation (SNP) | VAF 46/70 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs952338137, COSV63143156; called by muse, mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 14/96 reads (15%) | catalogued as rs754199513; called by mutect2, varscan2
- H3C2 | c.405_406del p.R135Sfs*12 | Frame Shift Del (DEL) | VAF 12/78 reads (15%) | catalogued as rs758780418; called by pindel, varscan2
- HCRTR1 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs200094994, COSV65485076; called by muse, mutect2, varscan2
- HLA-E | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100931995; called by muse, mutect2
- HOXA3 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 31/77 reads (40%) | catalogued as rs1248247321, COSV100415711; called by muse, mutect2, varscan2
- IFT80 | c.418A>G p.R140G | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100425141; called by muse, mutect2
- IKBIP | c.626del p.N209Ifs*3 | Frame Shift Del (DEL) | VAF 13/74 reads (18%) | catalogued as rs752553685; called by mutect2, pindel, varscan2
- IMPDH1 | c.520C>A p.L174I (on ENST00000470772 / NM_001142573.2; = p.L260I on NM_000883.4) | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.315); catalogued as COSV100118816; called by muse, mutect2
- INTS12 | c.1328A>G p.N443S | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.265); catalogued as rs1008278286, COSV100415936; called by muse, mutect2, varscan2
- IQCB1 | c.1282C>G p.L428V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as COSV100182158; called by muse, mutect2, varscan2
- IRF7 | c.1514T>C p.I505T (on ENST00000397566; = p.I492T on NM_001572.5) | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV99213483; called by muse, mutect2, varscan2
- KCND2 | c.13del p.V5Wfs*41 | Frame Shift Del (DEL) | VAF 16/100 reads (16%) | catalogued as COSV58583583, COSV58589056; called by mutect2, pindel, varscan2
- KCNMB4 | c.433C>A p.P145T | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as rs774714355, COSV50692622, COSV99253441; called by muse, mutect2, varscan2
- KIF1B | c.1582C>A p.P528T (on ENST00000377086 / NM_001365952.1; = p.P482T on NM_015074.3) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99824216; called by muse, mutect2, varscan2
- KLHL22 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.894); catalogued as COSV100186267; called by muse, mutect2
- KLHL36 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as COSV50724276; called by muse, mutect2, varscan2
- KRT17 | c.65del p.G22Afs*93 | Frame Shift Del (DEL) | VAF 9/80 reads (11%) | catalogued as rs753167272; called by mutect2, varscan2
- LAMA1 | c.7066A>G p.I2356V | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.056); catalogued as rs1272667332, COSV67537692; called by muse, mutect2
- LAMC1 | c.528G>T p.Q176H | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99280497; called by muse, mutect2, varscan2
- LCE5A | c.351C>A p.C117* | Nonsense Mutation (SNP) | VAF 22/117 reads (19%) | catalogued as COSV100524324; called by muse, mutect2, varscan2
- LMAN2L | c.187+1G>A p.X63_splice | Splice Site (SNP) | VAF 14/80 reads (18%) | catalogued as COSV99383640; called by muse, mutect2
- LSM14B | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 51/84 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs765003627, COSV99444802; called by muse, mutect2, varscan2
- LSMEM2 | c.415_417del p.E139del | In Frame Del (DEL) | VAF 10/58 reads (17%) | catalogued as rs782244609; called by pindel, varscan2
- LTBP2 | c.4780G>A p.V1594M | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.706); catalogued as COSV100000969; called by muse, mutect2, varscan2
- LTBP4 | c.2760C>T p.D920= (on ENST00000308370 / NM_001042544.1; = p.D883= on NM_003573.2) | Splice Region (SNP) | VAF 7/67 reads (10%) | catalogued as COSV99199637; called by muse, mutect2, varscan2
- MAST4 | c.1975A>T p.M659L (on ENST00000403625 / NM_001164664.2; = p.M470L on NM_015183.3) | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as rs56013433, COSV99845905; called by muse, mutect2, varscan2
- MGA | c.7328T>C p.F2443S (on ENST00000219905 / NM_001164273.1; = p.F2234S on NM_001080541.2) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54948752; called by muse, mutect2, varscan2
- MKRN1 | c.435T>A p.N145K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV99751899; called by muse, mutect2, varscan2
- MRPL14 | c.352C>T p.R118* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | catalogued as rs1245122956, COSV100921054; called by muse, mutect2, varscan2
- MRTFA | c.1129C>A p.Q377K | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as COSV100844381; called by muse, mutect2, varscan2
- MUL1 | c.347T>C p.I116T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV99939456; called by muse, mutect2, varscan2
- MYOT | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV99296707; called by muse, mutect2
- NEB | c.17030T>C p.V5677A | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.989); catalogued as COSV51430387; called by muse, mutect2
- NETO1 | c.1057G>A p.V353M | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs752941626, COSV100199776; called by muse, mutect2, varscan2
- NID2 | c.3062G>A p.R1021H | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.79); catalogued as rs377464008; called by muse, mutect2, varscan2
- NME1 | c.218T>C p.V73A | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV99184099; called by muse, mutect2, varscan2
- NOS1AP | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 21/243 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs141560292, CM104093, COSV62639295; called by muse, mutect2
- NRK | c.1009del p.R337Dfs*8 | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | catalogued as rs1336364406; called by mutect2, pindel, varscan2
- OGDHL | c.2270T>C p.V757A | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.595); catalogued as COSV100934537; called by muse, mutect2, varscan2
- OR3A3 | c.752G>T p.G251V | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99351556; called by muse, mutect2, varscan2
- OR56A1 | c.629T>C p.L210P | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100360561; called by muse, mutect2
- OR5B12 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs139365126; called by muse, mutect2, varscan2
- PARD3B | c.3124C>G p.P1042A (on ENST00000406610 / NM_001302769.2; = p.P973A on NM_057177.7) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs777727815, COSV100595313; called by muse, mutect2, varscan2
- PBRM1 | c.4135C>T p.R1379W (on ENST00000296302 / NM_001366071.2; = p.R1327W on NM_018313.5) | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56277669; called by muse, mutect2
- PCDHB7 | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.392); catalogued as COSV99177421; called by muse, mutect2, varscan2
- PCGF3 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1407477560, COSV100745493; called by muse, mutect2, varscan2
- PCYT1B | c.856A>G p.I286V | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.109); catalogued as COSV100770871; called by muse, mutect2, varscan2
- PDZRN4 | c.2689G>A p.G897R (on ENST00000402685 / NM_001164595.2; = p.G639R on NM_013377.4) | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1268969019, COSV100114718, COSV54206067; called by muse, mutect2
- PHACTR4 | c.2097C>A p.Y699* (on ENST00000373839 / NM_001350159.2; = p.Y709* on NM_023923.4) | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as COSV100868498; called by muse, mutect2, varscan2
- PIGM | c.296T>C p.F99S | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100928071; called by muse, mutect2
- PIGU | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99466883; called by muse, mutect2
- PIGZ | c.1467del p.T490Lfs*10 | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | catalogued as rs759867499; called by mutect2, pindel, varscan2
- PIK3CB | c.2391G>T p.E797D | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100006135; called by muse, mutect2, varscan2
- PLXNA3 | c.1967G>A p.W656* | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100860253; called by muse, mutect2, varscan2
- PNPLA5 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as rs775516746, COSV53373981; called by muse, mutect2, varscan2
- PPEF2 | c.153A>G p.I51M | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV99715012; called by muse, mutect2
- PRDM2 | c.104C>G p.S35C | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99342728; called by muse, mutect2
- PRKD1 | c.2371G>T p.D791Y | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1162341357, COSV100121565; called by muse, mutect2, varscan2
- PSIP1 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1487145673, COSV66254445; called by muse, mutect2, varscan2
- PTEN | c.981dup p.A328Sfs*3 | Frame Shift Ins (INS) | VAF 9/56 reads (16%) | catalogued as COSV64307595; called by mutect2, pindel, varscan2
- PTPRH | c.973C>A p.P325T | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.02); catalogued as COSV99671468; called by muse, mutect2
- RBM4B | c.169C>A p.H57N | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.02); catalogued as COSV100026549; called by muse, mutect2, varscan2
- RELN | c.6632G>A p.R2211H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374088118; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RFX4 | c.2021G>A p.R674H (on ENST00000392842 / NM_213594.3; = p.R580H on NM_032491.6) | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.964); catalogued as rs759847210, COSV99986372; called by muse, mutect2, varscan2
- RING1 | c.1034C>A p.P345H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV100761865; called by muse, mutect2
- RMC1 | c.1567C>T p.Q523* | Nonsense Mutation (SNP) | VAF 12/73 reads (16%) | catalogued as COSV99340436; called by muse, mutect2, varscan2
- RNF115 | c.781C>A p.L261M | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.611); catalogued as rs782021801, COSV100991918; called by muse, mutect2, varscan2
- SALL3 | c.3541C>T p.P1181S | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs952586199, COSV101610060; called by muse, mutect2, varscan2
- SDK1 | c.2070G>T p.W690C | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101268907; called by muse, mutect2
- SEMA6A | c.2008G>A p.V670I | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1307671471, COSV56715487; called by muse, mutect2, varscan2
- SEMA6B | c.826del p.R276Afs*11 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | catalogued as rs781437207, COSV56702141, COSV56702780; called by mutect2, pindel, varscan2
- SF3B3 | c.998T>A p.V333E | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100210258; called by muse, mutect2, varscan2
- SH2D2A | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100949193; called by muse, mutect2
- SHPRH | c.1327C>A p.R443S | Missense Mutation (SNP) | VAF 48/75 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51606998, COSV99262716; called by muse, mutect2, varscan2
- SIN3A | c.3185A>T p.N1062I | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100845238; called by muse, mutect2
- SLC22A14 | c.1766C>T p.T589I | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV99828367; called by muse, mutect2, varscan2
- SLC45A4 | c.634G>A p.V212M (on ENST00000517878 / NM_001286646.2; = p.V161M on NM_001080431.2) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.107); catalogued as rs747821881, COSV99200459; called by muse, mutect2
- SMAD3 | c.991G>A p.V331I | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as rs1320208623, COSV59280371; called by muse, mutect2, varscan2
- SPTB | c.5414C>T p.T1805M | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs142051792; called by muse, mutect2, varscan2
- SULT1A2 | c.743T>C p.M248T | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs1396076198, COSV100187359; called by muse, mutect2
- SYNE1 | c.16025C>T p.T5342M (on ENST00000367255 / NM_182961.4; = p.T5271M on NM_033071.3) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs202105931; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- SYNPO | c.1665del p.L556Wfs*23 (on ENST00000394243 / NM_001166208.2; = p.L312Wfs*23 on NM_007286.6) | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | catalogued as rs35729008; called by mutect2, pindel, varscan2
- TASOR2 | c.2585A>G p.H862R | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100051084, COSV60168753; called by muse, mutect2, varscan2
- TCEAL6 | c.112G>C p.A38P | Missense Mutation (SNP) | VAF 5/144 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.045); catalogued as COSV101036042, COSV65654008, COSV65654099; called by muse, mutect2
- TMEM108 | c.978G>T p.Q326H | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.605); catalogued as COSV100419638; called by muse, mutect2, varscan2
- TMEM161B | c.1138G>T p.A380S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.722); catalogued as COSV99680841; called by muse, mutect2, varscan2
- TOP1MT | c.1378C>T p.R460* | Nonsense Mutation (SNP) | VAF 77/127 reads (61%) | catalogued as rs776130476, COSV100239771, COSV61319452; called by muse, mutect2, varscan2
- TPCN1 | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as COSV100137098; called by muse, mutect2
- TRAF5 | c.1607C>T p.A536V | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV99807638; called by muse, mutect2, varscan2
- TRPV1 | c.1823C>T p.P608L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs199992542, COSV99440737; called by muse, varscan2
- TRRAP | c.2446C>T p.R816W | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62842499; called by muse, mutect2, varscan2
- VHL | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs773684010, COSV99846927; called by muse, mutect2
- VNN3 | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51591928, COSV99258712; called by muse, mutect2, varscan2
- WASHC4 | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 3/49 reads (6%) | catalogued as COSV100162778; called by muse, mutect2
- ZC3H14 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as rs774938890, COSV51773070; called by mutect2, varscan2
- ZIM3 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs142799493, COSV99075110; called by muse, mutect2, varscan2
- ZNF704 | c.1143G>T p.E381D | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100589893; called by muse, mutect2
- ZNF765 | c.1268A>T p.Q423L | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV101125578; called by muse, mutect2
- ADAMTS17 | c.3121del p.R1041Afs*5 | Frame Shift Del (DEL) | VAF 13/81 reads (16%) | called by mutect2, pindel, varscan2
- ADGRF5 | c.1432del p.D478Tfs*13 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel
- ARFGEF1 | c.3720del p.F1240Lfs*4 | Frame Shift Del (DEL) | VAF 11/82 reads (13%) | called by mutect2, pindel, varscan2
- ARHGEF40 | c.4459del p.H1487Tfs*15 | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | called by mutect2, pindel, varscan2
- BCL2L13 | c.543del p.F181Lfs*3 | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- CAPN12 | c.897dup p.R300Tfs*76 | Frame Shift Ins (INS) | VAF 16/91 reads (18%) | called by mutect2, pindel, varscan2
- CCL28 | c.351del p.K117Nfs*37 | Frame Shift Del (DEL) | VAF 29/162 reads (18%) | called by mutect2, pindel, varscan2
- CHD6 | c.7310del p.T2437Rfs*15 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | called by mutect2, pindel, varscan2
- CLP1 | c.964dup p.S322Ffs*27 | Frame Shift Ins (INS) | VAF 5/50 reads (10%) | called by mutect2, pindel
- EIF1B | c.140_144del p.V47Gfs*5 | Frame Shift Del (DEL) | VAF 4/50 reads (8%) | called by mutect2, pindel
- HHIP | c.54_56del p.F19del | In Frame Del (DEL) | VAF 9/66 reads (14%) | called by pindel, varscan2
- KDM4A | c.2092del p.Q698Rfs*8 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | called by mutect2, pindel, varscan2
- MAL | c.26del p.G9Afs*47 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | called by mutect2, pindel, varscan2
- MFSD2B | c.408del p.F137Sfs*34 | Frame Shift Del (DEL) | VAF 17/94 reads (18%) | called by mutect2, pindel, varscan2
- MYO5A | c.4441_4443del p.K1481del | In Frame Del (DEL) | VAF 20/110 reads (18%) | called by pindel, varscan2
- NME5 | c.424_425del p.M142Vfs*3 | Frame Shift Del (DEL) | VAF 7/59 reads (12%) | called by mutect2, pindel, varscan2
- NOVA1 | c.1197del p.F399Lfs*7 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | called by mutect2, pindel, varscan2
- NYAP1 | c.1714del p.V572Cfs*2 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | called by mutect2, pindel, varscan2
- OR6C70 | c.304del p.Y102Tfs*12 | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | called by mutect2, pindel, varscan2
- PARK7 | c.318_319del p.A107Rfs*9 | Frame Shift Del (DEL) | VAF 10/82 reads (12%) | called by pindel, varscan2
- PIK3CA | c.314_316del p.V105del | In Frame Del (DEL) | VAF 16/34 reads (47%) | called by mutect2, varscan2
- S100Z | c.97del p.E33Nfs*2 | Frame Shift Del (DEL) | VAF 11/68 reads (16%) | called by mutect2, pindel, varscan2
- SIDT2 | c.196C>G p.R66G | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- SUPT20HL1 | c.1440del p.P482Hfs*41 | Frame Shift Del (DEL) | VAF 22/106 reads (21%) | called by mutect2, pindel, varscan2
- ZNF12 | c.696del p.F232Lfs*17 (on ENST00000405858 / NM_016265.4; = p.F194Lfs*17 on NM_006956.3) | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- ABCG4 | c.459G>T p.L153= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100267050; called by muse, mutect2, varscan2
- ALOX12B | c.1287C>A p.P429= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs1024279885, COSV100047747; called by muse, mutect2, varscan2
- AMBRA1 | c.3159C>T p.N1053= (on ENST00000458649 / NM_001367468.1; = p.N963= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as rs1429119847, COSV100095368; called by muse, mutect2
- AP1M2 | c.582C>T p.I194= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs375519564; called by muse, varscan2
- ARSJ | c.216C>T p.S72= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV100193167; called by muse, mutect2, varscan2
- ASXL1 | c.585C>T p.A195= | Silent (SNP) | VAF 67/107 reads (63%) | catalogued as rs557596857, COSV60107590; called by muse, mutect2, varscan2
- ATG4B | c.915G>A p.P305= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs534411323, COSV60353484; called by muse, mutect2, varscan2
- CYTH3 | c.735C>T p.N245= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV63437633, COSV63437955; called by muse, mutect2, varscan2
- EFHC1 | c.849T>C p.D283= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV100932153; called by muse, mutect2, varscan2
- EVPL | c.5163T>C p.C1721= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV101440976; called by muse, mutect2
- F8 | c.5919T>C p.H1973= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as COSV100811983; called by muse, mutect2, varscan2
- GJB6 | c.226C>T p.L76= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as rs180764573, COSV99576167; ClinVar: likely benign; called by muse, mutect2, varscan2
- GRM1 | c.3456C>T p.R1152= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99269028; called by muse, mutect2
- H3C13 | c.301C>T p.L101= | Silent (SNP) | VAF 9/314 reads (3%) | catalogued as rs782566358; called by muse, mutect2
- IGFBP1 | c.15C>T p.P5= | Silent (SNP) | VAF 34/66 reads (52%) | catalogued as COSV99298861; called by muse, mutect2, varscan2
- KCNQ5 | c.1911A>G p.S637= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV100570822; called by muse, mutect2
- KDM6B | c.3408C>T p.S1136= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV99642333; called by muse, mutect2
- KIAA1549L | c.5172C>T p.T1724= (on ENST00000321505; = p.T2021= on NM_012194.3) | Silent (SNP) | VAF 51/95 reads (54%) | catalogued as rs764488480, COSV58594452; called by muse, mutect2, varscan2
- KIF15 | c.1134C>T p.S378= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV100393270; called by muse, mutect2, varscan2
- KIF26B | c.2832C>T p.S944= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as rs1173546879, COSV100833465; called by muse, mutect2, varscan2
- KMO | c.1350C>T p.F450= | Silent (SNP) | VAF 64/84 reads (76%) | catalogued as COSV100087887; called by muse, mutect2, varscan2
- MAP3K21 | c.1050C>T p.L350= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as rs748802015, COSV100786312; called by muse, mutect2, varscan2
- METRNL | c.912C>T p.N304= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV100193862; called by muse, mutect2, varscan2
- MRPS5 | c.1122G>A p.R374= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV99721061; called by muse, mutect2
- MYO9B | c.6054G>A p.S2018= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs572227199, COSV99812631; called by muse, mutect2, varscan2
- NUDT10 | c.63G>A p.A21= | Silent (SNP) | VAF 72/196 reads (37%) | catalogued as COSV62854015; called by muse, varscan2
- PARP10 | c.1719C>T p.N573= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as rs967686723, COSV57296686; called by muse, mutect2, varscan2
- PCDH12 | c.678T>A p.G226= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV99191457; called by muse, mutect2
- PCDHA1 | c.1854G>A p.A618= | Silent (SNP) | VAF 10/162 reads (6%) | catalogued as rs543937372, COSV65374214; called by muse, mutect2
- PCDHA2 | c.1815G>A p.A605= | Silent (SNP) | VAF 14/187 reads (7%) | catalogued as rs545092682, COSV65370424; called by muse, mutect2
- PCNX1 | c.5361A>G p.S1787= | Silent (SNP) | VAF 5/73 reads (7%) | catalogued as COSV99457299; called by muse, mutect2
- PLEKHG4 | c.2088G>A p.A696= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs201092570, COSV100431234; called by mutect2, varscan2
- POLA2 | c.237T>C p.H79= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV55481399; called by muse, mutect2
- PTPRB | c.474A>G p.Q158= | Silent (SNP) | VAF 57/88 reads (65%) | catalogued as COSV99719014; called by muse, mutect2, varscan2
- RAB33A | c.327C>T p.N109= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as COSV99924472; called by muse, mutect2, varscan2
- RHD | c.174G>A p.A58= | Silent (SNP) | VAF 23/172 reads (13%) | catalogued as rs757261780, COSV100155291; called by muse, mutect2, varscan2
- RP1 | c.2718T>C p.A906= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV99608891; called by muse, mutect2, varscan2
- SLC9C2 | c.3294T>C p.S1098= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV100877021; called by muse, mutect2
- SMARCC1 | c.1998T>C p.I666= | Silent (SNP) | VAF 13/123 reads (11%) | catalogued as COSV99593515; called by muse, mutect2, varscan2
- SNAP91 | c.2484C>T p.A828= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs373507806; called by muse, mutect2, varscan2
- SORBS2 | c.3006A>G p.K1002= (on ENST00000284776 / NM_021069.5; = p.K568= on NM_003603.6) | Silent (SNP) | VAF 10/115 reads (9%) | catalogued as COSV99512853; called by muse, mutect2
- SOX17 | c.1209C>T p.S403= | Silent (SNP) | VAF 44/71 reads (62%) | catalogued as COSV99810858; called by muse, mutect2, varscan2
- SPEG | c.2301C>T p.R767= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV100405686; called by muse, mutect2, varscan2
- SPRYD4 | c.463C>T p.L155= | Silent (SNP) | VAF 4/94 reads (4%) | catalogued as COSV100358490; called by muse, mutect2
- TAF1L | c.2277G>A p.L759= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV99645430; called by muse, mutect2, varscan2
- TAX1BP1 | c.2298T>G p.P766= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV99387418; called by muse, mutect2, varscan2
- TGFB1I1 | c.735C>T p.R245= (on ENST00000394863 / NM_001042454.3; = p.R228= on NM_015927.4) | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV100691238; called by mutect2, varscan2
- TMPRSS15 | c.1056C>G p.G352= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV99519350; called by muse, mutect2, varscan2
- TRBC2 | c.33C>T p.V11= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs782344912; called by muse, mutect2, varscan2
- TRIM29 | c.1578T>C p.S526= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV100532031; called by muse, mutect2
- TRIM37 | c.2454C>T p.I818= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs752013260, COSV99233481; called by muse, mutect2, varscan2
- UBR5 | c.6264T>A p.V2088= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV99642428; called by muse, mutect2, varscan2
- VOPP1 | c.162C>A p.A54= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV99567604; called by muse, mutect2
- VPS13C | c.5670C>A p.S1890= (on ENST00000644861 / NM_020821.3; = p.S1847= on NM_017684.5) | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV99830276; called by muse, mutect2
- VPS8 | c.1350C>T p.S450= (on ENST00000625842 / NM_001349294.1; = p.S448= on NM_015303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV99804053; called by mutect2, varscan2
- ZNF423 | c.1338G>A p.Q446= (on ENST00000563137 / NM_001379286.1; = p.Q438= on NM_015069.4) | Silent (SNP) | VAF 9/101 reads (9%) | catalogued as COSV99283854; called by muse, mutect2
- ZNF668 | c.1506C>T p.G502= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV56213737; called by muse, mutect2, varscan2
- DCHS2 | n.108dup | RNA (INS) | VAF 8/51 reads (16%) | called by mutect2, pindel, varscan2
- LARS2 | c.*1065del | 3'UTR (DEL) | VAF 12/70 reads (17%) | catalogued as rs774219507; called by mutect2, pindel, varscan2
- MCF2L | c.369-511G>A | Intron (SNP) | VAF 12/52 reads (23%) | catalogued as rs376527555; called by muse, mutect2, varscan2
- OBSCN | c.11660-2533A>G | Intron (SNP) | VAF 29/217 reads (13%) | catalogued as COSV99484451; called by muse, mutect2, varscan2
- PRCC | c.1084-555A>T | Intron (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- UBE2D2 | c.24+432C>T | Intron (SNP) | VAF 9/73 reads (12%) | catalogued as rs1486677461, COSV99551502; called by muse, mutect2, varscan2
